Somatic mutation profile of tumor specimen 0DL0JX from CCDI case PBBYVA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 11.6 years (4,229 days).
Specimen 0DL0JX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a457effe-2db2-4240-befc-2eb203805ead.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DL0IV (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e22810e0-fe19-4b74-8ab0-d95c0aab7348

The open-access MAF lists 15 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 3, Intron 2, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GPR75 | c.1253A>G p.N418S | Missense Mutation (SNP) | VAF 37/790 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.591); catalogued as rs1372792161; called by muse, mutect2
- LUZP1 | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 163/769 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as rs745524128, COSV56498513; called by muse, mutect2, varscan2
- MEIOC | c.2755G>C p.V919L | Missense Mutation (SNP) | VAF 36/580 reads (6%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV59519408; called by muse, mutect2
- NF1 | c.7537C>T p.Q2513* (on ENST00000358273 / NM_001042492.3; = p.Q2492* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 56/304 reads (18%) | catalogued as CM143478; called by muse, mutect2, varscan2
- SP3 | c.443A>C p.N148T | Missense Mutation (SNP) | VAF 28/588 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV59469983; called by muse, mutect2
- CTAG2 | c.434C>A p.A145D | Missense Mutation (SNP) | VAF 24/398 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.147); called by muse, mutect2
- ISM1 | c.482G>T p.W161L | Missense Mutation (SNP) | VAF 21/403 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2
- ISM2 | c.1703C>T p.A568V | Missense Mutation (SNP) | VAF 21/387 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.153); called by muse, mutect2
- SHPRH | c.838G>A p.V280M | Missense Mutation (SNP) | VAF 29/488 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- HS3ST4 | c.363C>T p.P121= | Silent (SNP) | VAF 24/373 reads (6%) | called by muse, mutect2
- SIGLEC12 | c.1767C>A p.S589= (on ENST00000291707 / NM_053003.4; = p.S471= on NM_033329.2) | Silent (SNP) | VAF 43/683 reads (6%) | catalogued as rs755647696, COSV52463733; called by muse, mutect2
- VRTN | c.639C>T p.H213= | Silent (SNP) | VAF 114/481 reads (24%) | catalogued as rs755174109, COSV56442662; called by muse, mutect2, varscan2
- FLNA | c.6379+45C>A | Intron (SNP) | VAF 23/535 reads (4%) | called by muse, mutect2
- TULP1 | c.191-95C>G | Intron (SNP) | VAF 10/108 reads (9%) | called by muse, mutect2
- VSTM4 | c.*15C>G | 3'UTR (SNP) | VAF 12/306 reads (4%) | called by muse, mutect2
